Gene-level copy-number profile of tumor specimen TCGA-D1-A1NU-01A from TCGA case TCGA-D1-A1NU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.7 years (27,272 days).
Specimen TCGA-D1-A1NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.05232d31-7107-4a58-bc70-3a7ef04c1ed1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A1NU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3213f43-ce38-46ad-be0c-6f94225841d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 17,234; copy number 2: 37,987; copy number 3: 4,086; copy number 4: 55; copy number 5: 200; copy number 6: 113; copy number 8: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A1NU-01A-11D-A14F-01): tumor purity 0.87, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,426,263–212,426,360, 1 gene: MIR548F2.
- chr14:106,037,902–106,875,071, 130 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 321 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:41,931,599–42,025,302, 3 genes, copy number 5 (within-gene range 2–5): LINC01914, C2orf91, AC013480.1.
- chr3:13,650,696–13,746,638, 1 gene, copy number 5: LINC00620.
- chr3:168,902,194–169,038,416, 4 genes, copy number 8: LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:172,039,578–173,141,235, 20 genes, copy number 5 (within-gene range 3–5): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16.
- chr4:37,073,681–37,700,002, 8 genes, copy number 6: AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA.
- chr8:36,987,977–43,544,057, 171 genes, copy number 5–8 (broad region; genes not listed).
- chr8:101,686,547–101,689,093, 1 gene, copy number 5: AP000426.1.
- chr8:140,636,281–141,195,808, 8 genes, copy number 5 (within-gene range 3–5): ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr22:24,270,817–27,460,060, 105 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
